Somatic mutation profile of tumor specimen TCGA-55-8301-01A (aliquot TCGA-55-8301-01A-11D-2284-08) from TCGA case TCGA-55-8301, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.0 years (21,535 days).
Specimen TCGA-55-8301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fce196c-b38d-487a-b7d2-58c0f1bb24d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8301-10A (Blood Derived Normal), aliquot TCGA-55-8301-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51fa21b0-c1aa-4509-8957-4db955a9bcff

The open-access MAF lists 307 somatic variants for this specimen: 224 protein-altering or splice-affecting, 75 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 75, Splice Site 9, Nonsense Mutation 8, Frame Shift Del 6, Frame Shift Ins 3, Intron 3, RNA 2, 3'Flank 1, 5'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ILDR1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as rs387907017, CM110961, COSV99878565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9249G>C p.E3083D | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV101447018; called by muse, mutect2, varscan2
- ABCD2 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100429614; called by muse, mutect2, varscan2
- ACIN1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as rs752145244, COSV99399861; called by muse, mutect2, varscan2
- ACP2 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs765762417, COSV99922308, COSV99922352; called by muse, mutect2, varscan2
- ACTN3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101557855; called by muse, mutect2
- ACTRT1 | c.177A>T p.Q59H | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100947652; called by muse, mutect2, varscan2
- ADAM28 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739151; called by muse, mutect2, varscan2
- ADAMTS12 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100711296; called by muse, mutect2, varscan2
- ADGRB3 | c.2379G>T p.R793S | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV101001069, COSV65398952; called by muse, mutect2, varscan2
- AGL | c.1011A>T p.Q337H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV99649558; called by muse, mutect2, varscan2
- AHR | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619949, COSV99620072; called by muse, mutect2, varscan2
- AMER3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200636300, COSV100366224, COSV58467211; called by muse, mutect2, varscan2
- ANKRD30A | c.3557A>T p.Q1186L (on ENST00000611781; = p.Q1130L on NM_052997.2) | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100653885; called by muse, mutect2, varscan2
- ANKRD35 | c.2549G>T p.G850V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100841776; called by muse, mutect2, varscan2
- ARMC3 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99958463; called by muse, mutect2, varscan2
- ASIC4 | c.549T>A p.S183R | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.484); catalogued as COSV100761794; called by muse, mutect2
- B3GAT2 | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.987); catalogued as COSV100017163, COSV57638347; called by muse, mutect2, varscan2
- BBS7 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99144988; called by muse, mutect2, varscan2
- BRDT | c.2169G>T p.Q723H | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100746494; called by muse, mutect2
- C10orf71 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.308); catalogued as COSV100110345; called by muse, mutect2, varscan2
- C5orf51 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs202010427; called by muse, mutect2, varscan2
- CAMK2B | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV51666449, COSV99323226; called by muse, mutect2
- CD5L | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100941085, COSV63822939; called by muse, mutect2
- CDC20 | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV100196544; called by muse, mutect2
- CDK17 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340925840, COSV99702851; called by muse, mutect2, varscan2
- CEACAM4 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701113; called by muse, mutect2
- CEACAM4 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701115; called by muse, mutect2
- CEP112 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781683706, COSV101210877; called by muse, mutect2, varscan2
- CETN1 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59121814, COSV59121981; called by muse, mutect2, varscan2
- CFH | c.1519+5_1519+8del p.X507_splice | Splice Site (DEL) | VAF 16/119 reads (13%) | catalogued as rs768316446; called by pindel, varscan2
- CHD5 | c.3627G>A p.M1209I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV99314184; called by muse, mutect2, varscan2
- CHM | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 5/144 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100753462; called by muse, mutect2
- CNBD2 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV62586663; called by muse, mutect2, varscan2
- CNTNAP5 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101443772, COSV70502003; called by muse, mutect2
- CNTNAP5 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70475380, COSV70487382; called by muse, mutect2
- COL4A2 | c.2086G>T p.G696C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847409; called by muse, mutect2, varscan2
- COL4A4 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307211; called by muse, mutect2
- COL6A6 | c.3413G>C p.G1138A | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650506, COSV100651033; called by muse, mutect2, varscan2
- CPD | c.2471C>A p.T824N | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99853023; called by muse, mutect2
- CRB1 | c.3928G>T p.G1310C | Missense Mutation (SNP) | VAF 143/514 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1411240510, COSV100957957; called by muse, mutect2, varscan2
- CRYBA1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs747710866, COSV56601235; called by muse, mutect2
- CSMD3 | c.6934C>A p.L2312I (on ENST00000297405 / NM_001363185.1; = p.L2208I on NM_052900.3) | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV99834425, COSV99839050; called by muse, mutect2, varscan2
- CUL1 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100296760; called by muse, mutect2, varscan2
- CYP20A1 | c.851-1G>T p.X284_splice | Splice Site (SNP) | VAF 15/144 reads (10%) | catalogued as COSV100619080; called by muse, mutect2, varscan2
- DISP3 | c.3529A>C p.I1177L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV53824680, COSV99609210; called by muse, mutect2, varscan2
- DNAI3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99642060; called by muse, mutect2, varscan2
- DPEP3 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV99262783; called by muse, mutect2, varscan2
- DSPP | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV99217587, COSV99218012; called by muse, mutect2, varscan2
- EHD3 | c.677C>A p.T226K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); catalogued as COSV100434781, COSV59029271; called by muse, mutect2, varscan2
- EIF2AK3 | c.2204A>G p.E735G | Missense Mutation (SNP) | VAF 107/743 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100303903; called by muse, mutect2, varscan2
- EML5 | c.4103T>G p.I1368S (on ENST00000380664; = p.I1376S on NM_183387.3) | Missense Mutation (SNP) | VAF 6/176 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100715900; called by muse, mutect2
- ENPP5 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 5/139 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV100040520; called by muse, mutect2
- ESRRB | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV99835492; called by muse, mutect2, varscan2
- EVI5 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100945400; called by muse, mutect2, varscan2
- F5 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100889164; called by muse, mutect2, varscan2
- FABP7 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV62956398, COSV62956788; called by muse, mutect2, varscan2
- FAM135B | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99417167, COSV99425393; called by muse, mutect2
- FBXO30 | c.2112G>C p.L704F | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395273; called by muse, mutect2
- FGF18 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51125936, COSV99209366; called by muse, varscan2
- FOXF2 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV99453350; called by muse, mutect2, varscan2
- FPR1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as rs756639389, COSV59053047; called by muse, mutect2, varscan2
- FRMD8 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV53684486, COSV99587359; called by muse, mutect2, varscan2
- FRS3 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as rs1312525816, COSV99442941; called by muse, mutect2, varscan2
- FSIP2 | c.16811C>A p.S5604Y | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100555585; called by muse, mutect2, varscan2
- GABRA6 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV99194692; called by muse, mutect2, varscan2
- GALNT10 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.854); catalogued as COSV99769424; called by muse, mutect2, varscan2
- GALNTL6 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV101550708; called by muse, mutect2, varscan2
- GAS2 | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99535333; called by muse, mutect2, varscan2
- GJC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746106098, COSV57910469; called by muse, mutect2, varscan2
- GLG1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99216015; called by muse, mutect2, varscan2
- GLRA1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51021642; called by muse, mutect2, varscan2
- GNAO1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341428; called by muse, mutect2, varscan2
- GNAO1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341430; called by muse, mutect2, varscan2
- GPR63 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193431397, COSV100013441; called by muse, mutect2
- GPR85 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775227; called by muse, mutect2, varscan2
- GRM8 | c.2648G>T p.S883I | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV100284213; called by muse, mutect2, varscan2
- GUCY1A2 | c.1826G>C p.R609T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV56486985, COSV99975435; called by muse, mutect2, varscan2
- HBG2 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100400659; called by muse, mutect2, varscan2
- HEATR1 | c.5548G>C p.E1850Q | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100857701; called by muse, mutect2
- HECW1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 10/137 reads (7%) | catalogued as COSV101223948; called by muse, mutect2
- HHAT | c.1370G>A p.W457* | Nonsense Mutation (SNP) | VAF 52/774 reads (7%) | catalogued as COSV99805077; called by muse, mutect2
- HSPA4L | c.429+2T>G p.X143_splice | Splice Site (SNP) | VAF 17/113 reads (15%) | catalogued as rs1403264456, COSV99613258; called by muse, mutect2, varscan2
- IFI35 | c.376-1G>A p.X126_splice (on ENST00000415816 / NM_001330230.2; = p.X128_splice on NM_005533.5) | Splice Site (SNP) | VAF 83/401 reads (21%) | catalogued as COSV99887875; called by muse, mutect2, varscan2
- IMPG1 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100886493, COSV64059379; called by muse, mutect2, varscan2
- INO80 | c.1522A>T p.I508F | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.969); catalogued as COSV100731928; called by muse, mutect2
- INTS6 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV100247162, COSV60879931; called by muse, mutect2, varscan2
- ITLN2 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.109); catalogued as COSV100600734; called by muse, mutect2
- ITPR2 | c.2125A>G p.I709V | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as rs1565671102, COSV101190061; called by muse, mutect2, varscan2
- ITPRID1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100086827; called by muse, mutect2, varscan2
- JHY | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99913417; called by muse, mutect2, varscan2
- KCNC2 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100129229; called by muse, mutect2
- KCNH1 | c.1684G>C p.D562H (on ENST00000271751 / NM_172362.3; = p.D535H on NM_002238.4) | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99657250, COSV99660033; called by muse, mutect2, varscan2
- KCNH5 | c.1938G>T p.L646F | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100527148; called by muse, mutect2, varscan2
- KCNK18 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as rs754933928, COSV100572086, COSV57972102; called by muse, mutect2, varscan2
- KCNMB1 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99211269; called by muse, mutect2
- KCNMB2 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100843981; called by muse, mutect2, varscan2
- KCNN3 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV99678703; called by muse, mutect2, varscan2
- KCNQ1 | c.1500C>G p.I500M | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV99327543; called by muse, mutect2
- KIAA1586 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs995121171, COSV100875365; called by muse, mutect2
- KIF2B | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99275708; called by muse, mutect2, varscan2
- KLRK1 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1486458343, COSV99555185; called by muse, mutect2, varscan2
- KRTAP11-1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV100190717; called by muse, mutect2, varscan2
- KRTAP13-4 | c.174del p.A59Pfs*27 | Frame Shift Del (DEL) | VAF 22/164 reads (13%) | catalogued as rs1295704834; called by mutect2, pindel, varscan2
- LAMA5 | c.8638G>T p.G2880W | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53360447; called by muse, mutect2
- LRFN2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV100599540; called by muse, mutect2, varscan2
- LRRN4CL | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99042307; called by muse, mutect2, varscan2
- LTA | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV101403215; called by muse, varscan2
- MACF1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 16/350 reads (5%) | catalogued as COSV100485326; called by muse, mutect2
- MAGI2 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835257; called by muse, mutect2, varscan2
- MAP11 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100385562; called by muse, mutect2
- MED12L | c.2462C>A p.S821Y | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99853779; called by muse, mutect2, varscan2
- MME | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100852444, COSV64709309; called by muse, mutect2, varscan2
- MMP16 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV54171928; called by muse, mutect2
- MUC16 | c.16419G>C p.Q5473H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); catalogued as COSV101200368; called by muse, mutect2, varscan2
- MUC5AC | c.14227C>A p.P4743T | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.81); catalogued as rs773599532, COSV100611501; called by muse, mutect2, varscan2
- MYO18B | c.4078A>G p.K1360E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100124255; called by muse, mutect2
- MYRF | c.1687A>C p.N563H (on ENST00000278836 / NM_001127392.3; = p.N554H on NM_013279.4) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99607380; called by muse, mutect2
- NAALAD2 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100428590, COSV58967171; called by muse, mutect2, varscan2
- NKX2-1 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100701955; called by muse, mutect2, varscan2
- NLRP12 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100145480; called by muse, mutect2
- NOTCH1 | c.6899G>T p.G2300V | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.186); catalogued as rs1330611000, COSV99489567; called by muse, mutect2, varscan2
- NPSR1 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 88/450 reads (20%) | catalogued as COSV100706676, COSV62200082; called by muse, mutect2, varscan2
- NRG1 | c.112C>A p.L38M (on ENST00000523534; = p.L185M on NM_013962.2) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.991); catalogued as COSV101584999; called by muse, mutect2
- OR10R2 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as COSV100936795, COSV63769138; called by muse, mutect2, varscan2
- OR14K1 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 134/587 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315306; called by muse, mutect2, varscan2
- OR2T10 | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100393747, COSV57896453; called by muse, mutect2, varscan2
- OR2T34 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100170422; called by muse, mutect2, varscan2
- OR4A5 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs765694224, COSV100157192; called by muse, mutect2, varscan2
- OR4C16 | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100114139; called by muse, mutect2, varscan2
- OR4K13 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100237793; called by muse, mutect2, varscan2
- OR4N5 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100374137; called by muse, mutect2, varscan2
- OR4S2 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746892, COSV56747956; called by muse, mutect2, varscan2
- OR52D1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59488112; called by muse, mutect2
- OR52D1 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100495253; called by muse, mutect2
- OR52E8 | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 58/496 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV101190543; called by muse, varscan2
- OR52K2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100355785; called by muse, mutect2, varscan2
- OR8H2 | c.760A>T p.T254S | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.26); catalogued as COSV100542394; called by muse, mutect2
- P2RY10 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 90/257 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99409215; called by muse, mutect2, varscan2
- PAN3 | c.2384+1G>T p.X795_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99144955; called by muse, mutect2, varscan2
- PANX1 | c.326dup p.Y111Lfs*37 | Frame Shift Ins (INS) | VAF 10/79 reads (13%) | catalogued as rs1234025755; called by mutect2, pindel, varscan2
- PARVG | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796105; called by muse, mutect2
- PCDH11Y | c.3570C>A p.H1190Q | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV99291946; called by muse, mutect2, varscan2
- PCDHGA12 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV99341075; called by muse, mutect2
- PCNX1 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99456260; called by muse, mutect2
- PDZD8 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100559562, COSV57825338; called by muse, varscan2
- PDZD8 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100559564; called by muse, varscan2
- PIP | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV52122118; called by muse, mutect2, varscan2
- PKP1 | c.963C>G p.N321K | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99825439; called by muse, mutect2, varscan2
- PKP3 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs772575836, COSV100520898; called by muse, mutect2, varscan2
- PLEKHA6 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1308797356, COSV99692358; called by muse, mutect2
- PLXNB2 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100834149; called by muse, mutect2, varscan2
- POU4F2 | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99850658; called by muse, mutect2
- PPP1R16B | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239663; called by muse, mutect2
- PRRC2B | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100621938, COSV61936074; called by muse, mutect2, varscan2
- PTPN13 | c.5535G>T p.M1845I (on ENST00000411767 / NM_080683.3; = p.M1826I on NM_006264.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100365060; called by muse, mutect2, varscan2
- PYHIN1 | c.1126T>A p.C376S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100932373; called by muse, mutect2, varscan2
- RAB23 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs771703421, COSV100443833; called by muse, mutect2, varscan2
- RBM22 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV99556065; called by muse, mutect2, varscan2
- RDH8 | c.88A>T p.I30F (on ENST00000651512; = p.I10F on NM_015725.4) | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99319230; called by muse, mutect2, varscan2
- RFX7 | c.952G>T p.V318F (on ENST00000559447 / NM_001368074.1; = p.V415F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100429021; called by muse, mutect2
- RGS6 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100666543; called by muse, mutect2, varscan2
- RGS7 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.355); catalogued as COSV100777167; called by muse, mutect2, varscan2
- RPTOR | c.2485G>T p.V829L | Missense Mutation (SNP) | VAF 151/547 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100156633, COSV60806746; called by muse, mutect2, varscan2
- SALL1 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.046); catalogued as COSV51761840, COSV99174971; called by muse, mutect2
- SCG3 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99591047; called by muse, mutect2, varscan2
- SENP7 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 21/450 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100053499; called by muse, mutect2
- SKAP2 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs371274766; called by muse, mutect2, varscan2
- SLC17A6 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54138850, COSV99581843; called by muse, mutect2, varscan2
- SLC17A6 | c.1413+1G>A p.X471_splice | Splice Site (SNP) | VAF 11/189 reads (6%) | catalogued as COSV99581848; called by muse, mutect2
- SLC22A9 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99655059, COSV99655138; called by muse, mutect2, varscan2
- SLC4A8 | c.2448G>T p.K816N | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100177157; called by muse, mutect2
- SLITRK1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV101000003; called by muse, mutect2, varscan2
- SMC1A | c.1142_1144del p.E381del | In Frame Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs797045991; called by pindel, varscan2
- SMPD3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs746072742, COSV54715385; called by muse, mutect2, varscan2
- SNRNP200 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100107794, COSV60493073; called by muse, mutect2, varscan2
- SPRR3 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV99768666; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 5/106 reads (5%) | PolyPhen probably damaging (0.993); catalogued as COSV99398547; called by muse, mutect2
- SYT14 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV55054401; called by muse, mutect2, varscan2
- TAF1L | c.5219G>T p.G1740V | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); catalogued as COSV99644962; called by muse, mutect2, varscan2
- TASOR2 | c.7123C>A p.L2375I | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100050662, COSV100051161; called by muse, mutect2, varscan2
- THSD7B | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99753908; called by muse, mutect2
- TMEM38A | c.533A>T p.N178I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99495344; called by muse, mutect2, varscan2
- TMPRSS15 | c.1022-1G>C p.X341_splice | Splice Site (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99518420; called by muse, mutect2
- TNFAIP3 | c.987-1G>T p.X329_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99396946; called by muse, mutect2, varscan2
- TNN | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99512365; called by muse, mutect2, varscan2
- TWNK | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV99272760; called by muse, mutect2, varscan2
- UGGT1 | c.1898T>C p.V633A | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV99390888; called by muse, mutect2, varscan2
- UPK1A | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 39/158 reads (25%) | catalogued as COSV99721925, COSV99722065; called by muse, mutect2, varscan2
- USP31 | c.1942T>C p.F648L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99565469; called by muse, mutect2
- VPS26B | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 6/190 reads (3%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV99845108; called by muse, mutect2
- VPS50 | c.2882G>C p.R961T | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100005023; called by muse, mutect2
- WDFY3 | c.180+1G>T p.X60_splice | Splice Site (SNP) | VAF 18/149 reads (12%) | catalogued as COSV99884313; called by muse, mutect2, varscan2
- WRN | c.1264A>T p.T422S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99989386; called by muse, mutect2, varscan2
- XKR6 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100440875, COSV58657714; called by muse, mutect2, varscan2
- XYLT1 | c.2252G>T p.R751M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99762404; called by muse, mutect2
- ZBTB43 | c.1142T>A p.F381Y | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100991421; called by muse, mutect2, varscan2
- ZC3H3 | c.2486G>C p.G829A | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99368143; called by muse, mutect2, varscan2
- ZEB1 | c.2632G>T p.V878L | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.07); catalogued as COSV100314643; called by muse, mutect2, varscan2
- ZEB2 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV100356411; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2176A>G p.M726V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100048366; called by muse, mutect2, varscan2
- ZMYND11 | c.341T>A p.I114K | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100556673; called by muse, mutect2, varscan2
- ZNF251 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52957046, COSV99478644; called by muse, varscan2
- ZNF251 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV99478646; called by muse, mutect2
- ZNF521 | c.1806G>T p.R602S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.392); catalogued as COSV100832678; called by muse, mutect2, varscan2
- ZNF521 | c.1805G>T p.R602M | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); catalogued as COSV100832679, COSV64130808; called by muse, mutect2, varscan2
- ZNF556 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100298808, COSV100298817; called by muse, mutect2, varscan2
- ZNF677 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100448040; called by muse, mutect2, varscan2
- ASAH2 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C2CD2L | c.1495dup p.D499Gfs*69 | Frame Shift Ins (INS) | VAF 17/178 reads (10%) | called by mutect2, pindel
- FCGBP | c.10424G>C p.G3475A | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAREM1 | c.1738del p.V580Sfs*22 (on ENST00000269209 / NM_001242409.2; = p.V579Sfs*22 on NM_022751.3) | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- LAMA2 | c.3752del p.G1251Afs*24 | Frame Shift Del (DEL) | VAF 41/218 reads (19%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.1605del p.S536Hfs*45 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- NRG1 | c.1073G>T p.G358V (on ENST00000405005 / NM_013964.5; = p.G363V on NM_013956.5) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2
- OR5W2 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.05); called by muse, mutect2
- PCARE | c.2679del p.S894Afs*7 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1215C>G p.S405R | Missense Mutation (SNP) | VAF 75/490 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.188); called by muse, varscan2
- PRKCD | c.731del p.C244Lfs*12 | Frame Shift Del (DEL) | VAF 29/185 reads (16%) | called by mutect2, pindel, varscan2
- SNRPN | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SPTA1 | c.736dup p.W246Lfs*30 | Frame Shift Ins (INS) | VAF 25/158 reads (16%) | called by mutect2, pindel, varscan2
- TPTE | c.304G>C p.V102L (on ENST00000618007 / NM_199261.4; = p.V84L on NM_199259.4) | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- ACKR1 | c.213G>T p.L71= | Silent (SNP) | VAF 61/311 reads (20%) | catalogued as COSV100929609; called by muse, mutect2, varscan2
- ANK2 | c.6012T>C p.S2004= | Silent (SNP) | VAF 39/273 reads (14%) | catalogued as COSV100002595; called by muse, mutect2, varscan2
- ANO5 | c.723A>G p.L241= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV100202000; called by muse, mutect2, varscan2
- ASZ1 | c.1323A>G p.E441= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99498116; called by muse, mutect2, varscan2
- BRD9 | c.1251A>G p.T417= | Silent (SNP) | VAF 121/312 reads (39%) | catalogued as COSV100057327; called by muse, mutect2, varscan2
- CEP170B | c.3897C>T p.A1299= (on ENST00000453495; = p.A1228= on NM_015005.3) | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs372160666; called by muse, mutect2, varscan2
- CMTM2 | c.582C>A p.I194= | Silent (SNP) | VAF 29/324 reads (9%) | catalogued as COSV51748237, COSV99216517; called by muse, mutect2
- CNBD1 | c.1203C>A p.S401= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs755403144, COSV101582163; called by muse, mutect2, varscan2
- CSPG5 | c.1653T>G p.G551= (on ENST00000383738 / NM_001206943.2; = p.G524= on NM_006574.4) | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as COSV99273927; called by muse, mutect2
- DNAH17 | c.3319A>C p.R1107= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV101102767; called by muse, mutect2, varscan2
- EIF4G3 | c.4539A>G p.A1513= | Silent (SNP) | VAF 19/238 reads (8%) | catalogued as COSV99944838; called by muse, mutect2
- FAM174A | c.222G>T p.A74= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100444510; called by muse, varscan2
- FREM1 | c.3012T>C p.L1004= | Silent (SNP) | VAF 72/411 reads (18%) | catalogued as COSV101084906; called by muse, mutect2, varscan2
- FSIP2 | c.18966G>T p.V6322= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100555586; called by muse, mutect2
- GABBR2 | c.939C>A p.G313= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99410603; called by muse, mutect2, varscan2
- GAGE10 | c.72G>T p.G24= | Silent (SNP) | VAF 112/334 reads (34%) | catalogued as COSV101340021; called by muse, mutect2
- GLRA1 | c.348C>A p.S116= | Silent (SNP) | VAF 41/269 reads (15%) | catalogued as COSV99199612; called by muse, mutect2, varscan2
- GRIA2 | c.294T>C p.N98= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as COSV99645072, COSV99645665; called by muse, mutect2, varscan2
- HSD3B2 | c.717G>T p.L239= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as COSV101027517; called by muse, mutect2, varscan2
- IGHA1 | c.892C>T p.L298= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- INPP4B | c.177G>A p.L59= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99525383; called by muse, mutect2
- INPP5K | c.81G>T p.A27= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV100233820; called by muse, mutect2, varscan2
- KDM5A | c.3231G>T p.R1077= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV101238960; called by muse, mutect2
- KIAA1210 | c.3057C>A p.P1019= | Silent (SNP) | VAF 92/236 reads (39%) | catalogued as rs867373321, COSV101274286; called by muse, mutect2, varscan2
- KRTAP10-2 | c.372T>C p.S124= | Silent (SNP) | VAF 77/405 reads (19%) | catalogued as COSV100554433; called by muse, mutect2, varscan2
- LPA | c.1110C>T p.C370= | Silent (SNP) | VAF 32/702 reads (5%) | catalogued as rs778620376; called by muse, mutect2
- LRP2 | c.9429C>A p.L3143= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as COSV99789353; called by muse, mutect2, varscan2
- MAB21L1 | c.732G>T p.G244= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as COSV100081891; called by muse, mutect2, varscan2
- MC1R | c.390C>T p.S130= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as rs1413538674, COSV100205663, COSV100205947; called by muse, mutect2, varscan2
- MED13 | c.4296A>G p.A1432= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as rs750830333, COSV101181170, COSV101181223; called by muse, mutect2, varscan2
- MID2 | c.1578T>C p.P526= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV53310031; called by muse, mutect2, varscan2
- MME | c.789C>T p.P263= | Silent (SNP) | VAF 72/281 reads (26%) | catalogued as COSV100852445; called by muse, mutect2, varscan2
- MUC5B | c.12087T>G p.T4029= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as rs1381644455; called by muse, mutect2, varscan2
- MYO10 | c.3738G>A p.L1246= | Silent (SNP) | VAF 71/524 reads (14%) | catalogued as COSV99945770; called by muse, mutect2, varscan2
- MYO1F | c.2778G>T p.T926= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100596840; called by muse, mutect2, varscan2
- NDST4 | c.1758C>A p.S586= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99997012; called by muse, mutect2
- NEB | c.14883T>C p.Y4961= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV51465554; called by muse, mutect2
- NMUR1 | c.630G>T p.R210= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100532035; called by muse, mutect2, varscan2
- NUP210 | c.4890G>C p.V1630= | Silent (SNP) | VAF 51/231 reads (22%) | catalogued as COSV99596508; called by muse, mutect2, varscan2
- NXPE4 | c.1431C>A p.I477= (on ENST00000375478 / NM_001077639.2; = p.I193= on NM_017678.3) | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV100970495; called by muse, mutect2
- OR10Q1 | c.237C>A p.T79= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs767381023, COSV100372166, COSV57470440; called by muse, mutect2
- OR51S1 | c.388C>A p.R130= | Silent (SNP) | VAF 49/295 reads (17%) | catalogued as COSV100437542; called by muse, mutect2, varscan2
- OR5AN1 | c.195T>C p.S65= | Silent (SNP) | VAF 78/401 reads (19%) | catalogued as COSV100004396; called by muse, mutect2, varscan2
- OR8B4 | c.120G>T p.V40= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV100635838; called by muse, mutect2, varscan2
- OTOF | c.843C>T p.D281= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as rs368728682; ClinVar: uncertain significance; called by muse, mutect2
- PDLIM7 | c.444G>A p.L148= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100730264; called by muse, mutect2
- PDZRN3 | c.1080C>T p.T360= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as rs370653708; called by muse, mutect2, varscan2
- PIP4P2 | c.48C>T p.S16= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs774256514, COSV53438938, COSV99575442; called by muse, mutect2, varscan2
- PPP2R2C | c.819C>T p.N273= | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as COSV100160690; called by muse, mutect2, varscan2
- RABL6 | c.219C>T p.I73= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61040373; called by muse, mutect2
- RNASE9 | c.180T>A p.P60= | Silent (SNP) | VAF 46/279 reads (16%) | catalogued as COSV100141289; called by muse, mutect2, varscan2
- RNF145 | c.1260C>T p.T420= (on ENST00000424310 / NM_001199383.2; = p.T448= on NM_144726.2) | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV99193705; called by muse, mutect2, varscan2
- RPS6KA5 | c.1497A>G p.E499= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV100002802; called by muse, mutect2
- SAMD3 | c.84A>G p.E28= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV100148311; called by muse, mutect2, varscan2
- SEL1L2 | c.1998C>T p.H666= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs200162045, COSV53157714, COSV99532809; called by muse, mutect2, varscan2
- SEMA4C | c.2280G>T p.S760= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV100561072; called by muse, mutect2
- SERPINA12 | c.294C>A p.I98= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs755761050, COSV100369734; called by muse, mutect2, varscan2
- SF3B1 | c.1089A>C p.P363= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV100135085, COSV59215184; called by muse, mutect2
- SLC43A3 | c.693C>T p.T231= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100725226; called by muse, mutect2, varscan2
- SLCO3A1 | c.268C>T p.L90= | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as COSV100575363; called by muse, mutect2
- SNRNP200 | c.1218G>T p.R406= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100107793; called by muse, mutect2, varscan2
- SNX29 | c.903C>T p.V301= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as COSV100029324; called by muse, mutect2
- SPEF2 | c.2709A>T p.A903= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as COSV100607958; called by muse, mutect2, varscan2
- SPEN | c.10191G>T p.T3397= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV100999038; called by muse, mutect2, varscan2
- STKLD1 | c.1620G>A p.Q540= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV64241844; called by muse, mutect2, varscan2
- SYT14 | c.543C>A p.P181= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99655574; called by muse, mutect2, varscan2
- TBC1D23 | c.84A>C p.A28= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100792670; called by mutect2, varscan2
- TCEAL9 | c.105A>G p.L35= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV101012046; called by muse, mutect2, varscan2
- TIMM9 | c.126A>G p.K42= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV99374121; called by muse, mutect2, varscan2
- TRPA1 | c.846G>A p.Q282= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as COSV100083830, COSV100084568; called by muse, mutect2, varscan2
- VPS13D | c.9078A>T p.S3026= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV99167420; called by muse, mutect2, varscan2
- ZFHX4 | c.10668A>G p.S3556= | Silent (SNP) | VAF 29/225 reads (13%) | catalogued as COSV99264748; called by muse, mutect2, varscan2
- ZFP36L2 | c.336G>A p.L112= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1454242860, COSV99143958; called by muse, mutect2, varscan2
- ZNF415 | c.591C>T p.F197= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV54699360; called by muse, mutect2, varscan2
- ZNF99 | c.1929T>C p.H643= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV101233874; called by mutect2, varscan2
- AP000769.3 | chr11:65504248 del AA | 5'Flank (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- DCHS2 | n.7438T>A | RNA (SNP) | VAF 19/155 reads (12%) | catalogued as COSV100602093; called by muse, mutect2, varscan2
- GABRG2 | c.1249-629C>T | Intron (SNP) | VAF 29/186 reads (16%) | catalogued as rs756617271; called by muse, mutect2, varscan2
- MIR1915 | chr10:21495795 G>A | 3'Flank (SNP) | VAF 21/72 reads (29%) | catalogued as rs772110448, COSV101008156; called by muse, mutect2, varscan2
- MIR525 | n.64del | RNA (DEL) | VAF 28/153 reads (18%) | called by mutect2, pindel, varscan2
- OR52D1 | c.-2G>C | 5'UTR (SNP) | VAF 6/116 reads (5%) | catalogued as rs1296661680, COSV100495252; called by muse, mutect2
- PTPRN2 | c.113-43003C>A | Intron (SNP) | VAF 34/231 reads (15%) | catalogued as COSV101133254; called by muse, mutect2
- PTPRN2 | c.113-43004C>A | Intron (SNP) | VAF 34/228 reads (15%) | catalogued as COSV101133255; called by muse, mutect2
